Somatic mutation profile of tumor specimen TARGET-10-PAUAYB-09A (aliquot TARGET-10-PAUAYB-09A-01D) from TARGET case TARGET-10-PAUAYB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.3 years (6,682 days).
Specimen TARGET-10-PAUAYB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d37805f6-e5f0-4a2c-97bc-10b5ec8aeafa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUAYB-14A (Bone Marrow Normal), aliquot TARGET-10-PAUAYB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab0d7caa-7d07-41d1-a849-923bd291811b

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, In Frame Ins 1, Frame Shift Ins 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT4 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as rs756451392, COSV57336642; called by muse, mutect2, varscan2
- BICDL2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756953090, COSV54156700; called by muse, mutect2, varscan2
- CADM2 | c.823G>A p.V275I (on ENST00000407528 / NM_001167674.2; = p.V277I on NM_153184.4) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV67381108; called by muse, mutect2, varscan2
- CCSER1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs372007893; called by muse, mutect2, varscan2
- CDH2 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV52283268, COSV52285516, COSV99295737; called by muse, mutect2, varscan2
- IL7R | c.730_731insGGCGCTGTTCAT p.T244delinsRRCSS | In Frame Ins (INS) | VAF 22/62 reads (35%) | catalogued as COSV57405359, COSV57406723, COSV57407745, COSV57409353, COSV57414512; called by mutect2, pindel, varscan2
- KDM6A | c.3144+5G>A | Splice Region (SNP) | VAF 30/37 reads (81%) | catalogued as COSV65041458; called by muse, mutect2, varscan2
- MYB | c.40_41insGGCC p.E14Gfs*4 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | catalogued as COSV57198855, COSV57201532, COSV57203337; called by mutect2, pindel*, varscan2*
- MYB | c.203A>T p.N68I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV57198869; called by muse, mutect2, varscan2
- POU2F3 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV52794699; called by muse, mutect2, varscan2
- PHF6 | c.130_137del p.K44Afs*12 | Frame Shift Del (DEL) | VAF 46/48 reads (96%) | called by mutect2, varscan2
- CNTLN | c.3375A>G p.K1125= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- NEB | c.6468C>A p.T2156= | Silent (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- HELZ2 | c.570+99C>T | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as rs776348786; called by muse, mutect2, varscan2
